Somatic mutation profile of tumor specimen 0DBW4F from CCDI case PBBLUN, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Desmoplastic fibroma; Tissue or organ of origin: Pleura, NOS; Age at diagnosis: 8.1 years (2,948 days).
Specimen 0DBW4F: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 92eed159-268f-4859-98a3-4ab54fc7ffd5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DBW3Z (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1c0ca698-b6cc-4409-b645-cd9ff680aee7

The open-access MAF lists 3 somatic variants for this specimen: 3 protein-altering or splice-affecting.
By variant classification: Missense Mutation 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.133T>C p.S45P | Missense Mutation (SNP) | VAF 195/760 reads (26%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as rs121913407, COSV62687880, COSV62689248, COSV62696859; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CC2D2B | c.1373C>T p.S458L | Missense Mutation (SNP) | VAF 205/778 reads (26%) | SIFT tolerated (0.19); PolyPhen benign (0.129); called by muse, mutect2, varscan2
- TNR | c.799C>T p.P267S | Missense Mutation (SNP) | VAF 52/278 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.031); called by muse, mutect2, varscan2
